Somatic mutation profile of tumor specimen MMRF_1744_1_BM_CD138pos (aliquot MMRF_1744_1_BM_CD138pos_T1_KBS5U_L04791) from MMRF case MMRF_1744, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 68.4 years (24,968 days).
Specimen MMRF_1744_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dcdd6129-a4f1-4d6c-b831-d2bc10f91417.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1744_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1744_1_PB_Whole_C3_KBS5U_L04804; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe0b7069-5145-46f7-a835-d0004a09f5ca

The open-access MAF lists 76 somatic variants for this specimen: 24 protein-altering or splice-affecting, 10 silent, 42 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 23, Missense Mutation 22, Intron 14, Silent 10, 3'Flank 2, 5'Flank 2, Nonsense Mutation 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP4X1 | c.1216G>A p.V406M | Missense Mutation (SNP) | VAF 92/173 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs371700658; called by muse, mutect2, varscan2
- IGHV2-70 | c.261G>C p.R87S | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as rs371189824; called by muse, varscan2
- LIMCH1 | c.36G>T p.Q12H | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs867406306; called by muse, mutect2, varscan2
- RNMT | c.1105C>A p.P369T | Missense Mutation (SNP) | VAF 39/40 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100054370; called by muse, mutect2, varscan2
- SDK2 | c.659C>G p.P220R | Missense Mutation (SNP) | VAF 27/28 reads (96%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as COSV66180583; called by muse, mutect2, varscan2
- TRIM10 | c.1034C>T p.P345L | Missense Mutation (SNP) | VAF 59/124 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.067); catalogued as rs1347319768; called by muse, mutect2, varscan2
- UNC5D | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 90/121 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1182849801; called by muse, mutect2, varscan2
- WIPF1 | c.377C>T p.P126L | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV55811516; called by muse, mutect2, varscan2
- CACNA1H | c.2602A>T p.S868C | Missense Mutation (SNP) | VAF 94/193 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2
- CARNMT1 | c.1187A>C p.Y396S | Missense Mutation (SNP) | VAF 101/203 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- CERS1 | c.775T>C p.F259L | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- CILK1 | c.117T>G p.F39L | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- GPATCH8 | c.414T>A p.C138* | Nonsense Mutation (SNP) | VAF 58/60 reads (97%) | called by muse, mutect2, varscan2
- HDAC10 | c.1079A>G p.Q360R | Missense Mutation (SNP) | VAF 121/256 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- IGLV5-45 | c.337T>G p.Y113D | Missense Mutation (SNP) | VAF 83/229 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KIF1B | c.5284G>A p.V1762M (on ENST00000377086 / NM_001365952.1; = p.V1716M on NM_015074.3) | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- OSR1 | c.577C>T p.H193Y | Missense Mutation (SNP) | VAF 55/128 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PSMB7 | c.795G>C p.E265D | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC5A8 | c.1219G>T p.G407* | Nonsense Mutation (SNP) | VAF 30/73 reads (41%) | called by muse, mutect2, varscan2
- SVOP | c.1204A>T p.T402S | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- TCF7L2 | c.286A>C p.K96Q | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- UBE4B | c.1058C>T p.P353L | Missense Mutation (SNP) | VAF 81/158 reads (51%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZBTB9 | c.56C>G p.A19G | Missense Mutation (SNP) | VAF 84/181 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ZNF235 | c.1455A>C p.K485N | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CNTRL | c.5337A>G p.Q1779= | Silent (SNP) | VAF 97/209 reads (46%) | catalogued as rs780192321; called by muse, mutect2, varscan2
- EFCAB13 | c.2313C>T p.V771= | Silent (SNP) | VAF 16/24 reads (67%) | catalogued as rs773535214, COSV58947441; called by muse, mutect2, varscan2
- HOXD13 | c.180G>A p.A60= | Silent (SNP) | VAF 28/73 reads (38%) | catalogued as rs1284683098; called by muse, mutect2, varscan2
- ISOC1 | c.51G>A p.G17= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as rs756158264; called by muse, mutect2, varscan2
- MLPH | c.420C>T p.S140= | Silent (SNP) | VAF 25/51 reads (49%) | catalogued as COSV52822627; called by muse, mutect2, varscan2
- REV3L | c.18A>C p.I6= | Silent (SNP) | VAF 57/190 reads (30%) | called by muse, mutect2, varscan2
- RREB1 | c.2328C>T p.C776= | Silent (SNP) | VAF 65/139 reads (47%) | called by muse, mutect2, varscan2
- RUNDC3A | c.1299G>A p.V433= | Silent (SNP) | VAF 28/60 reads (47%) | catalogued as rs889060807; called by muse, varscan2
- ZBTB4 | c.1527T>G p.T509= | Silent (SNP) | VAF 40/104 reads (38%) | called by muse, mutect2, varscan2
- ZFHX2 | c.2991T>A p.A997= | Silent (SNP) | VAF 77/175 reads (44%) | called by muse, mutect2, varscan2
- ADAM22 | chr7:88199262 del A | 3'Flank (DEL) | VAF 52/98 reads (53%) | called by mutect2, pindel, varscan2
- ADAMTS17 | c.*1597T>G | 3'UTR (SNP) | VAF 51/89 reads (57%) | called by muse, mutect2, varscan2
- API5 | c.70-201A>G | Intron (SNP) | VAF 4/73 reads (5%) | called by muse, mutect2
- ATG5 | c.*1237G>A | 3'UTR (SNP) | VAF 66/141 reads (47%) | called by muse, mutect2, varscan2
- ATN1 | c.*319G>A | 3'UTR (SNP) | VAF 17/49 reads (35%) | catalogued as rs1357297767; called by muse, mutect2, varscan2
- BIN2 | chr12:51324526 C>T | 5'Flank (SNP) | VAF 8/20 reads (40%) | called by muse, mutect2, varscan2
- CCL5 | c.*36T>A | 3'UTR (SNP) | VAF 94/334 reads (28%) | called by muse, mutect2, varscan2
- CLCN1 | c.774+460G>A | Intron (SNP) | VAF 51/139 reads (37%) | called by muse, mutect2, varscan2
- CTSD | c.69-18C>A | Intron (SNP) | VAF 35/117 reads (30%) | called by muse, mutect2, varscan2
- EMC1 | c.*2456C>T | 3'UTR (SNP) | VAF 8/17 reads (47%) | called by muse, mutect2, varscan2
- FGB | c.*303C>T | 3'UTR (SNP) | VAF 59/138 reads (43%) | catalogued as rs886059142; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FRMD3 | c.1196-18688A>C | Intron (SNP) | VAF 75/173 reads (43%) | called by muse, mutect2, varscan2
- GMFB | c.*918T>A | 3'UTR (SNP) | VAF 10/167 reads (6%) | called by muse, mutect2
- GOLIM4 | c.-338T>C | 5'UTR (SNP) | VAF 30/182 reads (16%) | called by muse, mutect2, varscan2
- HORMAD2 | c.*618C>A | 3'UTR (SNP) | VAF 45/128 reads (35%) | called by muse, mutect2, varscan2
- HP1BP3 | c.*590T>C | 3'UTR (SNP) | VAF 44/91 reads (48%) | catalogued as rs546162510; called by muse, mutect2, varscan2
- HRH1 | c.*2764G>A | 3'UTR (SNP) | VAF 17/35 reads (49%) | called by muse, mutect2, varscan2
- IGHJ6 | chr14:105863439 T>C | 5'Flank (SNP) | VAF 10/16 reads (63%) | catalogued as rs141217017; called by muse, varscan2
- IPCEF1 | chr6:154154574 C>G | 3'Flank (SNP) | VAF 32/74 reads (43%) | called by muse, mutect2
- IRX6 | c.*122A>T | 3'UTR (SNP) | VAF 10/224 reads (4%) | catalogued as COSV99306297; called by muse, mutect2
- MECR | c.*43C>A | 3'UTR (SNP) | VAF 25/58 reads (43%) | called by muse, mutect2, varscan2
- MED13L | c.5588+88A>C | Intron (SNP) | VAF 17/39 reads (44%) | called by muse, mutect2, varscan2
- NFASC | c.*2440G>A | 3'UTR (SNP) | VAF 54/165 reads (33%) | called by muse, mutect2, varscan2
- NPEPPS | c.1875+52C>A | Intron (SNP) | VAF 147/184 reads (80%) | called by muse, mutect2, varscan2
- NRG3 | c.823+1658C>A | Intron (SNP) | VAF 19/31 reads (61%) | called by muse, mutect2, varscan2
- PDLIM5 | c.96+1414G>A | Intron (SNP) | VAF 71/160 reads (44%) | called by muse, mutect2, varscan2
- PLCB1 | c.3423+12045A>G | Intron (SNP) | VAF 63/150 reads (42%) | called by muse, mutect2, varscan2
- PNPLA2 | c.*322del | 3'UTR (DEL) | VAF 32/72 reads (44%) | called by mutect2, pindel, varscan2
- RASGRF2 | c.*146C>T | 3'UTR (SNP) | VAF 32/107 reads (30%) | called by muse, mutect2, varscan2
- RUNDC3A | c.1199-376G>C | Intron (SNP) | VAF 58/129 reads (45%) | called by muse, mutect2, varscan2
- RUNDC3A | c.1199-243G>T | Intron (SNP) | VAF 25/47 reads (53%) | called by muse, mutect2, varscan2
- RUNDC3A | c.*135G>T | 3'UTR (SNP) | VAF 16/44 reads (36%) | called by muse, varscan2
- SCN9A | c.*2129A>G | 3'UTR (SNP) | VAF 13/134 reads (10%) | called by muse, mutect2
- SF1 | c.*286A>G | 3'UTR (SNP) | VAF 37/87 reads (43%) | called by muse, mutect2, varscan2
- SIRT2 | c.*296G>A | 3'UTR (SNP) | VAF 28/90 reads (31%) | called by muse, mutect2, varscan2
- SNX19 | c.*1584T>G | 3'UTR (SNP) | VAF 16/36 reads (44%) | called by muse, mutect2
- STXBP2 | c.1453-69G>A | Intron (SNP) | VAF 6/19 reads (32%) | catalogued as rs953187797; called by muse, mutect2, varscan2
- TECPR1 | c.*2238_*2248del | 3'UTR (DEL) | VAF 57/164 reads (35%) | called by mutect2, pindel, varscan2
- TESMIN | c.917+1605T>G | Intron (SNP) | VAF 64/126 reads (51%) | called by muse, mutect2, varscan2
- TTC17 | c.160-30G>A | Intron (SNP) | VAF 19/39 reads (49%) | catalogued as rs371922266; called by muse, mutect2, varscan2
- UBXN7 | c.*3559G>A | 3'UTR (SNP) | VAF 44/102 reads (43%) | called by muse, mutect2, varscan2
- VGLL3 | c.*5787A>G | 3'UTR (SNP) | VAF 48/105 reads (46%) | called by muse, mutect2, varscan2
